Surgical pathology report (de-identified scan), TCGA case TCGA-CM-5341, project TCGA-COAD (Colon Adenocarcinoma), tissue source site MSKCC, specimen TCGA-CM-5341-01A (Primary Tumor).

[page 1 of 5]
.....

Clinical Diagnosis & History:

PET avid lesions in sigmoid found as an incidental finding for evaluation of pneumonia. Colonoscopy with nearly obstructing 3 cm mass in sigmoid showing invasive adenocarcinoma with LV invasion.

Specimens Submitted:

- 1: SP: Sigmoid colon
- 2: SP: Proximal anastomotic ring
- 3: SP: Distal anastomotic ring

AMENDED DIAGNOSIS:

1. COLON, SIGMOID; RESECTION:
- TWO SEPARATE FOCI OF INVASIVE ADENOCARCINOMA.
- THE FIRST TUMOR IS MORE PROXIMAL, MOOERATELY DIFFERENTIATED, AND MEASURES 5.8 x 4.9 x 1.8 CM.
- IT SHOWS FOCAL TUMOR BUDDING AND INVADES INTO THE MUSCULARIS PROPRIA (pT2). THERE IS NO VASCULAR OR PERINEURAL INVASION.
- THE SECOND TUMOR IS 2.4 CM DISTAL TO THE FIRST, MOOERATELY DIFFERENTIATED, AND MEASURES 2.5 X 1.0 X 1.0 CM. IT CONSISTS PREOONINANTLY OF TUBULOVILLOOS ADENOMA WITH INTRAMUCOSAL CARCINOMA; HOWEVER, THE PREVIOUS BIOPSY OF THIS LESION DOCUMENTED SUBMUCOSAL INVASION (pT1) AND VASCULAR INVASION.
- METASTATIC CARCINOMA INVOLVES ONE OF EIGHTEEN LYMPH NOOES (1/18) (pN1).
- RESECTION MARGINS ARE NEGATIVE.
2. COLON, PROXIMAL ANASTOMOSIS RING, EXCISION:
- UNREMARKABLE COLONIC MUCOSA, NEGATIVE FOR CARCINOMA.
3. COLON, DISTAL ANASTOMOSIS RING, EXCISION:
- UNREMARKABLE COLONIC MUCOSA, NEGATIVE FOR CARCINOMA.

Note:

This document represents an amended version of the surgical pathology report originally issued on [REDACTED]. That report is superseded by the present

** Continued on next page **

[page 2 of 5]
document. The amendment consists of the following change:

ORIGINAL REPORT:

Specimen Submitted:

1. COLON, SIGMOID; RESECTION:
- TWO SEPARATE FOCI OF INVASIVE ADENOCARCINOMA.
- THE FIRST TUMOR IS MORE PROXIMAL, MODERATELY DIFFERENTIATED, AND MEASURES 5.8 x 4.9 x 1.8 CM.
- IT SHOWS FOCAL TUMOR BUDDING AND INVADES INTO THE MUSCULARIS PROPRIA (pT2). THERE IS NO VASCULAR OR PERINEURAL INVASION.
- THE SECOND TUMOR IS 2.4 CM DISTAL TO THE FIRST, MODERATELY DIFFERENTIATED, AND MEASURES 2.5 X 1.0 X 1.0 CM. IT CONSISTS PREDOMINANTLY OF TUBULOVILLOUS ADENOMA WITH INTRAMUCOSAL CARCINOMA; HOWEVER, THE PREVIOUS BIOPSY OF THIS LESION DOCUMENTED SUBMUCOSAL INVASION (pT1) AND VASCULAR INVASION.
- THERE IS ONE LYMPH NODE IDENTIFIED (1/18).
- RESECTION MARGINS ARE NEGATIVE.

AMENDED REPORT:

Specimen submitted:

1. COLON, SIGMOID; RESECTION:
- TWO SEPARATE FOCI OF INVASIVE ADENOCARCINOMA.
- THE FIRST TUMOR IS MORE PROXIMAL, MODERATELY DIFFERENTIATED, AND MEASURES 5.8 x 4.9 x 1.8 CM.
- IT SHOWS FOCAL TUMOR BUDDING AND INVADES INTO THE MUSCULARIS PROPRIA (pT2). THERE IS NO VASCULAR OR PERINEURAL INVASION.
- THE SECOND TUMOR IS 2.4 CM DISTAL TO THE FIRST, MODERATELY DIFFERENTIATED, AND MEASURES 2.5 X 1.0 X 1.0 CM. IT CONSISTS PREDOMINANTLY OF TUBULOVILLOUS ADENOMA WITH INTRAMUCOSAL CARCINOMA; HOWEVER, THE PREVIOUS BIOPSY OF THIS LESION DOCUMENTED SUBMUCOSAL INVASION (pT1) AND VASCULAR INVASION.
- METASTATIC CARCINOMA INVOLVES ONE OF EIGHTEEN LYMPH NODES (1/18) (pN1).
- RESECTION MARGINS ARE NEGATIVE.

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON THE PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL) BY THE PATHOLOGIST WHOSE NAME APPEARS ABOVE MINE, AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

*** Report Electronically signed Out ***

Gross Description:

** Continued on next page **

[page 3 of 5]
1). The specimen is received fresh and is labeled "sigmoid colon, suture distal ". It consists of a sigmoid colon that measures 19 cm in length and 7.5 cm in diameter. The serosal surface is intact. The specimen is opened to reveal two fungating tumors, measuring 2.5 x 1 cm (#1) and 5.8 x 4.9 cm (#2). Tumor #1 is located 2.4 cm distal from tumor #2 and is 4 cm from the distal margin and 15 cm from the proximal margin. Tumor #2 is located 5 cm from the distal margin and 5 cm from the proximal margin. Serial sectioning reveals tumor #2 invasion to be a depth of 1.8 cm, which is more than 3 cm from the serosal surface. Tumor #1 does not show gross invasion and appears to be confined to the stalk. A round tumor nodule with necrosis, measuring 1.5 x 1.5 x 1.5 cm is identified in the serosa beneath tumor #2 (discontinuous from the tumor). The remaining mucosa is unremarkable. Pericolic adipose tissue is submitted for lymph node dissection. Entire tumor #1 and representative sections of the remainder of the specimen are submitted. TPS is submitted.

Summary of sections:

PM - proximal margin
DM - distal margin
RM - radial margin
T1 - tumor#1
T2 - tumor#2
U - uninvolved mucosa
TN - tumor nodule
BLN - bisected lymph node

2). The specimen is received in formalin wrapped around an anastomotic pin, labeled "Proximal anastomotic ring" and consists of a ring of pink tan soft tissue measuring 2.5 x 2.5 x 1.4 cm. Multiple sutures and staples are attached. The mucosal surface is pink tan and focally hemorrhagic. The sutures and staples are removed and the soft tissue is entirely submitted.

Summary of sections:

U - undesignated

3). The specimen is received in formalin, labeled " distal anastomotic ring" and consists of a ring of pink tan soft tissue measuring 1.5 x 1.5 x 0.8 cm. Multiple sutures and staples are attached. The mucosal surface is pink tan and focally hemorrhagic. The sutures and staples are removed and the soft tissue is entirely submitted.

Summary of sections:

U - undesignated

Summary of Sections:

Part 1: SP: Sigmoid colon

** Continued on next page **

[page 4 of 5]
Block	Sect.	Site	PCs
5		ELN	9
1		DM	1
6		LN	18
1		PM	1
3		T1	3
5		T2	5
1		TN	1

Part 2: SP: Proximal anastomotic ring

Block	Sect.	Site	PCs
1		U	1

Part 3: SP: Distal anastomotic ring

Block	Sect.	Site	PCs
1		U	1

Amendments

Amend Date: [REDACTED]

Original Diagnosis:

1. COLON, SIGMOID; RESECTION:
- TWO SEPARATE FOCI OF INVASIVE ADENOCARCINOMA.
- THE FIRST TUMOR IS MORE PROXIMAL, MODERATELY DIFFERENTIATED, AND MEASURES 5.8 x 4.9 x 1.8 CM.
- IT SHOWS FOCAL TUMOR BUDDING AND INVADES INTO THE MUSCULARIS PROPRIA (pT2). THERE IS NO VASCULAR OR PERINEURAL INVASION.
- THE SECOND TUMOR IS 2.4 CM DISTAL TO THE FIRST, MODERATELY DIFFERENTIATED, AND MEASURES 2.5 X 1.0 X 1.0 CM. IT CONSISTS PREDOMINANTLY OF TUBULOVILLOUS ADENOMA WITH INTRAMUCOSAL CARCINOMA; HOWEVER, THE PREVIOUS BIOPSY OF THIS LESION DOCUMENTED SUBMUCOSAL INVASION (pT1) AND VASCULAR INVASION.
- THERE IS ONE LYMPH NODE IDENTIFIED (1/18).
- RESECTION MARGINS ARE NEGATIVE.
2. COLON, PROXIMAL ANASTOMOSIS RING, EXCISION:
- UNREMARKABLE COLONIC MUCOSA, NEGATIVE FOR CARCINOMA.
3. COLON, DISTAL ANASTOMOSIS RING, EXCISION:
- UNREMARKABLE COLONIC MUCOSA, NEGATIVE FOR CARCINOMA.

** Continued on next page **

[page 5 of 5]
*** Report Electronically Signed Out ***
Signed out by [REDACTED]

Referring Physician Contacted
[REDACTED] was notified via email on [REDACTED]

** End of Report **

Source: NCI Genomic Data Commons file 3083b7be-0fa6-495f-a99b-c468a9b5ee45 (TCGA-CM-5341.BD882C39-2D27-41A6-9A89-4482D92ED68B.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).